Somatic mutation profile of tumor specimen MBCProject_0026_T1_WES (aliquot MBCProject_0026_T1_WES_1) from CMI case MBCProject_0026, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.3 years (15,812 days).
Specimen MBCProject_0026_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95d8fb61-d2f3-4fcb-a4cd-5538eeac99b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0026_SALIVA (Saliva), aliquot MBCProject_0026_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f54e4e5-98fb-4327-b426-599a6d81acfe

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.3054G>T p.K1018N | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs1184990999, COSV64879429; called by muse, mutect2
- CATSPER4 | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as rs1403337106; called by muse, mutect2
- GATA3 | c.1187_1191del p.L396Qfs*109 | Frame Shift Del (DEL) | VAF 45/493 reads (9%) | called by mutect2, pindel
- KDM4C | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MAP3K1 | c.3137_3142del p.F1046_Q1048delins* | Nonsense Mutation (DEL) | VAF 18/204 reads (9%) | called by mutect2, pindel*
- MAP3K1 | c.4430del p.L1477Cfs*13 | Frame Shift Del (DEL) | VAF 41/404 reads (10%) | called by mutect2, pindel, varscan2
- MAST2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PARD6B | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 17/195 reads (9%) | called by muse, mutect2
- PLP2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF407 | c.2582G>T p.S861I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
